Gene-level copy-number profile of tumor specimen TCGA-A2-A0YI-01A from TCGA case TCGA-A2-A0YI, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 62.9 years (22,961 days).
Specimen TCGA-A2-A0YI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.9758cc40-6f04-4297-b933-dd2d0a938930.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0YI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6f71d30-7ea0-4a39-90c6-123946e94302

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,867; copy number 3: 84; copy number 4: 49,049; copy number 5: 146; copy number 6: 5,063; copy number 7: 280; copy number 8: 29; copy number 9: 164; copy number 11: 137.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0YI-01A-31D-A10L-01): tumor purity 0.44, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 301 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:53,506,237–58,784,048, 95 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr11:9,384,652–14,268,133, 97 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr11:17,695,010–18,408,425, 29 genes, copy number 9 (within-gene range 6–9): AC124301.1, LINC02729, MYOD1, KCNC1, SERGEF, AC055860.1, TPH1, SAAL1, HIGD1AP5, SAA3P, MRGPRX3, AC090099.1, AC090099.2, MRGPRX12P, MRGPRX4, GLTPP1, MRGPRX13P, SLC25A51P4, SAA4, SAA2-SAA4, SAA2, RNA5SP333, ST13P5, SAA1, RNA5SP334, HPS5, GTF2H1, MIR3159, LDHA.
- chr11:25,588,475–32,105,722, 79 genes, copy number 11 (broad region; genes not listed).
- chr11:32,132,657–32,143,723, 1 gene, copy number 11: AL078612.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
